Gene-level copy-number profile of tumor specimen C3N-02380-01 (profiled together with C3N-02380-02) from CPTAC case C3N-02380, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 56.1 years (20,483 days).
Specimen C3N-02380-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 923740d7-6868-461a-a5f6-8dc60322dfd1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02380-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/f6c2622e-51e0-40f4-b174-953383079f9e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 11,566; copy number 2: 39,876; copy number 3: 6,842; copy number 4: 348; copy number 5: 208; copy number 7: 6; copy number 8: 17; copy number 9: 41.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,724,512–1,745,992, 2 genes (within-gene range 0–1): AL031282.1, SLC35E2A.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 272 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:90,153,052–92,688,254, 29 genes, copy number 5–7: LINC01339, AC099554.1, AC093510.2, CETN3, AC093510.1, MBLAC2, POLR3G, LYSMD3, ADGRV1, TMEM251P1, LUCAT1, AC074132.1, AC093281.1, AC093281.2, RNU4-90P, AC123595.1, AC123595.2, Metazoa_SRP, AC008799.1, AC008799.2, ARRDC3, ARRDC3-AS1, RAB5CP2, PCBP2P3, AC093298.1, AC114316.1, AC124854.1, AC026780.1, AC026780.2.
- chr5:171,861,549–178,825,571, 185 genes, copy number 5 (broad region; genes not listed).
- chr5:180,100,795–181,342,213, 58 genes, copy number 8–9: RASGEF1C, AC104115.1, MAPK9, AC104115.2, AC008610.1, GFPT2, AC034213.1, RNU6-525P, CNOT6, AC122714.1, SCGB3A1, FLT4, AC122714.2, LINC02222, OR2AI1P, RNU1-17P, OR2Y1, MGAT1, AC022413.1, HEIH, LINC00847, AC022413.2, ZFP62, BTNL8, Y_RNA, RPS29P12, AC091874.2, AC091874.1, ARPP19P1, BTNL3, RNU6-1036P, BTNL9, MIR8089, AC008620.1, FOXO1B, AC008620.2, OR2V1, OR2V2, LINC01962, AC008443.4, TRIM7, TRIM7-AS1, AC008443.3, TRIM41, MIR4638, AC008443.1, RACK1, SNORD96A, SNORD95, CTC-338M12.4, TRIM52, TRIM52-AS1, AC008443.2, AC008443.5, RNU6-705P, AC138035.1, AC138035.3, AC138035.2.

Autosomal genes at a single copy (total copy number 1): 8,722. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
